Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A8MF, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A8MF-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Soc. Sec. #:

Physician(s):

Visit #:

Sex: Male

Location:

Accession #:

Service Date:

Received:

Client:

FINAL PATHOLOGIC DIAGNOSIS

A. Prostate and seminal vesicles, prostatectomy: Prostatic adenocarcinoma, Gleason score 3+4=7, bilateral involvement, present at surgical margins; see comment.

B. "Left posterior apical margin," biopsy:

1. No tumor.
2. Fibromuscular tissue.

C. "Left anterior apical margin," biopsy:

1. No tumor.
2. Benign prostate tissue.

D. Right pelvic lymph node, biopsy:

1. No tumor.
2. Fibrofatty tissue.

E. Left pelvic lymph nodes, dissection: No tumor (0/7).

COMMENT:

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Adenocarcinoma.
- **Location of tumor:** Left apex (slides A2 and A3), left posterior mid gland (slides A5 and A6), left anterior mid gland (slides A9-A12), left base (slide A16 and A18), right anterior apex (slides A1 and A2), right anterior midgland.
- **Estimated volume of tumor:** 6.2 cubic centimeters.
- **Gleason score:** 3+4=7.
- **Estimated volume > Gleason pattern 3:** 30%.
- **Involvement of capsule:** Tumor invades capsule (slides A1 and A3).
- **Extraprostatic extension:** Extraprostatic extension is present, extensive (slide A6 and A11).

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JW 11/23/14

[page 2 of 3]
- **Margin status for tumor:** Tumor extends to inked excision margins at apex, left lateral and base of main specimen, slides A2, A6, and A13. Separately submitted margins are negative for tumor.
- **Margin status for benign glands:** Benign glands present at inked extension margins; slide A2.
- **Involvement of seminal vesicle:** None.
- **Perineural infiltration:** Present (slide A5).
- **Prostatic intraepithelial neoplasia (PIN):** Absent.
- **AJCC/UICC stage:** pT3aN0MX.

Specimen(s) Received

A: Prostate and seminal vesicles (fresh)
B: Left posterior apical margin
C: Left anterior apical margin
D: Right pelvic lymph node
E: Left pelvic lymph node

Clinical History

Review of the electronic medical record indicates the patient is a [REDACTED] man with a history of prostate cancer by core biopsy, Gleason's grade from 3+3 (6) to 3+4 (7). He now undergoes a radical robot-assisted laparoscopic prostatectomy with bilateral pelvic lymph node dissection.

Gross Description

The specimen is received in five parts, each labeled with the patient's name and medical record number. Part A is received fresh, while Parts B-E are received in formalin.

Part A is additionally labeled "prostate and seminal vesicles." It consists of a large, intact prostate gland with attached seminal vesicle/vas deferens bundles, weighing 44 gm and measuring 3.8 cm from apex to base, 6 cm from medial to lateral, and 3.3 cm from anterior to posterior. The exterior of the specimen is roughened, red-tan, and glistening. A single line of small, silver-gray laparoscopic staples closes the dorsal vein complex. The bladder margin demonstrates extensive cautery markings. The seminal vesicle/vas deferens bundles are small, soft, and whorled, without obvious mass or lesion. The right anterior and lateral aspect of the mid gland through base is somewhat soft to palpation. The left lateral aspect from apex through mid gland is firm to palpation. The right anterior surface of the gland is inked in green, the left anterior surface is inked in blue, and the posterior surface is inked in black. The specimen is then partially bisected at the mid gland, perpendicular to the urethral channel, and fresh tissue is banked from the left posterior aspect of the apex through mid gland for tissue banking/research purposes. The incision is then glued shut, and the specimen is fixed prior to further sectioning. Following formalin fixation, the bladder margin is removed, and the remainder of the gland is serially sectioned, from apex to base, perpendicular to the urethral channel, into seven serial slices. The serial slices reveal a large, solid, white, lobular mass dominating the left central and peripheral zones, noted in the apical margin through serial slice 4. The tumor continues along the posterior aspect into serial slice 7. This lesion measures 3 cm in greatest dimension and grossly abuts the anterior, lateral, and posterior prostatic capsule in serial slices 1-4. The left anterior lateral and posterior aspect of the left lobe is dominated by an area of polycystic tissue. The apical and bladder margins as well as representative sections of the prostate and seminal vesicles are submitted as follows:

Apical margin

Cassette A1:	Right apex
Cassette A2:	Central apex.
Cassette A3:	Left apex.

Serial slice 2

Cassette A4:	Right lateral aspect.
Cassette A5:	Central aspect.
Cassette A6:	Left lateral aspect.

Serial slice 4

Cassette A7:	Right lateral aspect.
Cassette A8:	Right central aspect.
Cassette A9:	Left central aspect.

[page 3 of 3]
• Cassette A10: Left lateral aspect.
• Cassette A11: Anterior margin.
Serial slice 6
Cassette A12: Left posterior quadrant
Bladder margin
Cassettes A13-A16: Sequentially submitted from right to left.
Prostatic/Seminal vesicle junction
Cassette A17: Right seminal vesicle and cross-section of vas deferens.
Cassette A18: Left seminal vesicle and cross-section of vas deferens.

Part B, additionally labeled "1 - left posterior apical margin ink - margin side," consists of one pink-tan, oriented, firm, fibrous tissue fragment measuring 0.9 x 0.6 x 0.4 cm. One side of the specimen has been pre-inked black and is designated as margin by the submitting surgeon. The specimen is trisected and entirely submitted in cassette B1.

Part C, additionally labeled "2 - left anterior apical margin ink in true margin," consists of one pink-tan, oriented, firm, fibrous tissue fragment measuring 0.8 x 0.4 x 0.2 cm. One side has been pre-inked black and is designated the margin by the submitting surgeon. The specimen is trisected and entirely submitted in cassette C1.

Part D, additionally labeled "3 - right pelvic lymph nodes," consists of one soft, yellow-brown, irregular, unoriented, fibroadipose tissue fragment, including multiple lymph node candidates. The specimen measures 2.2 x 1.5 x 0.3 cm. The specimen is entirely submitted, intact, in cassette D1.

Part E, additionally labeled "4 - left pelvic lymph nodes," consists of one soft, yellow-brown, irregular, unoriented, fibroadipose tissue fragment measuring 6.5 x 2.8 x 0.6 cm. It grossly appears to contain multiple lymph node candidates that range from 0.3 to 2.8 cm in greatest diameter. The lymph node candidates are submitted as follows:

Cassette E1: Intact lymph node candidates.
Cassette E2: Intact lymph node candidates.
Cassettes E3-E4: Single, sectioned lymph node candidate, submitted in two cassettes.
The remaining tissue is returned to the container.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically signed out

Source: NCI Genomic Data Commons file ba6a12d0-9742-4e40-a96c-c72e98202642 (TCGA-V1-A8MF.C2A32E46-BB93-43E6-BF3A-995745161434.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).